Somatic mutation profile of tumor specimen TCGA-D8-A1JT-01A (aliquot TCGA-D8-A1JT-01A-31D-A13L-09) from TCGA case TCGA-D8-A1JT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.3 years (25,677 days).
Specimen TCGA-D8-A1JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8ecc725-1e30-4872-865b-e3877b9d332d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JT-10A (Blood Derived Normal), aliquot TCGA-D8-A1JT-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ceebfe0a-a63a-4391-aab4-be70edae319f

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Del 2, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOC | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV52025260; called by muse, mutect2, varscan2
- CASP4 | c.36G>C p.K12N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV67744578; called by muse, mutect2, varscan2
- CNTRL | c.6028G>A p.E2010K | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs980089330, COSV53049325; called by muse, mutect2, varscan2
- DCAF7 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.063); catalogued as COSV60408018; called by muse, mutect2, varscan2
- DHX37 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58136288; called by muse, mutect2, varscan2
- GALNT17 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61170332; called by muse, mutect2, varscan2
- GATA3 | c.1060del p.L354* | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as COSV60520516; called by mutect2, pindel, varscan2
- IFT74 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.377); catalogued as rs1032816767, COSV66259605; called by muse, mutect2, varscan2
- IREB2 | c.1413G>A p.K471= | Splice Region (SNP) | VAF 33/91 reads (36%) | catalogued as rs1001060279, COSV51924313; called by muse, mutect2, varscan2
- KALRN | c.8882G>A p.R2961H (on ENST00000360013 / NM_001024660.4; = p.R1264H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368942316, COSV52259354; called by muse, mutect2, varscan2
- LGR6 | c.647A>T p.H216L (on ENST00000367278 / NM_001017403.1; = p.H164L on NM_021636.3) | Missense Mutation (SNP) | VAF 134/195 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55160316; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV64056207; called by muse, mutect2, varscan2
- MUC16 | c.6812C>T p.T2271I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV67476652; called by muse, mutect2, varscan2
- NEK8 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs779175681, COSV52046183; called by muse, mutect2, varscan2
- OR6S1 | c.501G>T p.L167F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); catalogued as rs368643983, COSV100289238; called by muse, mutect2
- OR8S1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1435392519, COSV59599678; called by muse, mutect2, varscan2
- PCDHGB7 | c.797C>A p.A266D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53977612; called by muse, mutect2, varscan2
- PLK2 | c.1900_1902del p.I634del | In Frame Del (DEL) | VAF 30/170 reads (18%) | catalogued as rs764901947; called by pindel, varscan2
- POU3F4 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1354177998, COSV64537973; called by muse, mutect2, varscan2
- PSMD5 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs761479099, COSV52961175; called by muse, mutect2, varscan2
- RNF148 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV57371370; called by muse, mutect2, varscan2
- VCPIP1 | c.621T>G p.C207W | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV60048783; called by muse, mutect2, varscan2
- ZNF609 | c.952G>C p.V318L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58585982, COSV58587514; called by muse, mutect2, varscan2
- KMT2C | c.13939_13940del p.K4647Vfs*2 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- ADAM29 | c.1032G>A p.E344= | Silent (SNP) | VAF 59/89 reads (66%) | catalogued as COSV63662429; called by muse, mutect2, varscan2
- ARHGAP28 | c.1581A>G p.K527= (on ENST00000383472 / NM_001366230.1; = p.K368= on NM_001010000.3) | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99148231; called by muse, mutect2, varscan2
- CRIM1 | c.264G>C p.L88= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV54867279; called by muse, mutect2
- FAM174A | c.399C>G p.G133= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV57064238; called by mutect2, varscan2
- FAT1 | c.1527G>A p.P509= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs374215633; called by muse, mutect2, varscan2
- LINS1 | c.516T>A p.A172= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV59079725; called by muse, mutect2, varscan2
- RYR2 | c.1242C>G p.R414= | Silent (SNP) | VAF 34/247 reads (14%) | catalogued as COSV100771936, COSV63694876; called by muse, mutect2, varscan2
- TFF2 | c.243C>T p.C81= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV52295767; called by muse, mutect2, varscan2
- ZCWPW1 | c.1749A>T p.S583= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99546250; called by muse, mutect2, varscan2
- ZNF208 | c.981C>T p.T327= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs200969060; called by muse, mutect2, varscan2
- NOVA1 | c.519+1832G>A | Intron (SNP) | VAF 41/175 reads (23%) | catalogued as COSV57480731; called by muse, mutect2, varscan2
